Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LI, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LI-01A (Primary Tumor).

Procedure: adrenalectomy and vena cava tumor

Gross description: 17 x 12 x 20cm, 816g and 12cm vena cava tumor thrombus

Diagnosis: adrenocortical carcinoma

Reference Pathology:

Diagnosis: adrenocortical carcinoma

Weiss score: 6

Hough score: 4.52

Van Slooten score: 20.1

ICD-O-3
Carcinoma, adrenal cortical
8370/3
Site: Adrenal Gland Cortex
C74.0
JW 2/6/13

Reviewer Initials	Date of Review	

JW 1/16/13
1/16/13

Source: NCI Genomic Data Commons file 1efac890-eb98-4573-9e56-b36fbfd10613 (TCGA-OR-A5LI.087A53B3-572F-4492-8D19-7CFE41C8DA39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).